Somatic mutation profile of tumor specimen MP2PRT-PAWAVU-TMP1-A (aliquot MP2PRT-PAWAVU-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAWAVU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,541 days).
Specimen MP2PRT-PAWAVU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a778b09a-18d0-400f-aa73-e0245273730e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAVU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAVU-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da91dafb-10dd-4c9d-994c-4443f291a490

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 38/373 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CYFIP2 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.857); catalogued as COSV59029355; called by muse, mutect2, varscan2
- DNTTIP2 | c.1582A>G p.S528G | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV63283516; called by muse, mutect2, varscan2
- USH2A | c.3722C>A p.A1241D | Missense Mutation (SNP) | VAF 31/364 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1212720652, COSV56367039, COSV56368890; called by muse, mutect2
- ETV3 | c.400+5G>C | Splice Region (SNP) | VAF 93/240 reads (39%) | called by muse, mutect2, varscan2
- MAGEC2 | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 195/539 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- UBE4B | c.1696-1G>T p.X566_splice (on ENST00000343090 / NM_001105562.3; = p.X437_splice on NM_006048.5) | Splice Site (SNP) | VAF 108/237 reads (46%) | called by muse, mutect2
- C10orf71 | c.423C>A p.S141= | Silent (SNP) | VAF 44/394 reads (11%) | called by muse, varscan2
- LRRC55 | c.162G>A p.Q54= | Silent (SNP) | VAF 250/618 reads (40%) | called by muse, mutect2, varscan2
